Gene-level copy-number profile of tumor specimen ALCH-B2AO-TTP1-A from ALCHEMIST case ALCH-B2AO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,071 days).
Specimen ALCH-B2AO-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 334c63e9-6971-466b-80ec-4c0729d0b517.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2AO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/d09aedee-c39e-4d67-b1f5-8787a0afe727

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 164; copy number 1: 15,638; copy number 2: 40,333; copy number 3: 2,190; copy number 4: 61; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 159 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:203,090,654–203,186,704, 5 genes: ADORA1, AC105940.2, AC105940.1, MYBPH, CHI3L1.
- chr2:25,926,598–26,028,612, 3 genes: KIF3C, UQCRHP2, TRMT112P6.
- chr2:26,160,023–26,189,663, 3 genes: AC011742.1, PPIL1P1, GAREM2.
- chr2:47,035,279–47,040,524, 1 gene (within-gene range 0–2): AC093732.1.
- chr3:93,843,764–93,843,862, 1 gene: RNU6-488P.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:62,275,361–63,060,084, 4 genes: AC128676.1, RNU6-417P, AC069285.2, AC069285.3.
- chr7:63,509,303–63,510,165, 1 gene: PHKG1P2.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr10:42,149,310–42,149,549, 1 gene: KSR1P1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:54,591,480–55,271,114, 13 genes: OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4.
- chr11:60,756,867–60,875,693, 8 genes: MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1.
- chr14:18,333,726–18,419,273, 4 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:25,218,617–25,257,027, 20 genes (within-gene range 0–1): SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:73,319,859–73,368,958, 2 genes: HCN4, AC068397.2.
- chr16:35,722,268–35,912,516, 26 genes: AC106785.1, RNA5SP406, RNA5SP407, RNA5SP408, RNA5SP409, LINC02167, RNA5SP410, RNA5SP411, RNA5SP412, RNA5SP413, RNA5SP414, RNA5SP415, RNA5SP416, RNA5SP417, RNA5SP418, RNA5SP419, RNA5SP420, RNA5SP421, RNA5SP422, RNA5SP423, AC106785.2, HMGN2P41, VN1R70P, AC116553.1, AC116553.2, PPP1R1AP2.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:3,565,444–3,981,899, 22 genes: TRPV1, AC027796.5, AC027796.3, AC027796.1, SHPK, AC027796.2, CTNS, AC027796.4, TAX1BP3, P2RX5-TAX1BP3, AC132942.1, EMC6, P2RX5, ITGAE, AC116914.2, HASPIN, AC116914.1, NCBP3, CAMKK1, P2RX1, ATP2A3, LINC01975.
- chr17:6,451,263–6,556,555, 2 genes (within-gene range 0–1): PITPNM3, Metazoa_SRP.
- chr17:10,628,526–10,657,309, 1 gene: MYH3.
- chr17:32,265,832–32,324,659, 2 genes (within-gene range 0–2): RHBDL3, AC026620.1.
- chr18:37,234,119–37,762,131, 7 genes (within-gene range 0–2): AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1.
- chr19:24,162,370–24,163,425, 1 gene: AC073534.1.
- chr22:17,980,868–17,980,961, 1 gene (within-gene range 0–1): MIR648.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:41,072,945–41,101,056, 2 genes, copy number 5 (within-gene range 2–5): NFYA, AL031778.1.
- chr6:61,574,328–62,286,225, 4 genes, copy number 5: MTRNR2L9, KHDRBS2-OT1, KHDRBS2, AL355347.1.

Autosomal genes at a single copy (total copy number 1): 13,525. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
